Surgical pathology report (de-identified scan), TCGA case TCGA-61-1916, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1916-01A (Primary Tumor).

[page 1 of 2]
SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

- A. Laterality: 3
Right 2. Left 3. Bilateral
B. Procedure: 4
1. Cystectomy 4. TAH with salpingo-oophorectomy
2. Salpingo-oophorectomy 5. Other
3. Bilateral salpingo-oophorectomy

C. Tumor size (maximum dimension): 6.0 cm

- D. Histologic type: 1
1. Papillary serous tumor, BL* 12. Undifferentiated Carcinoma
2. Papillary serous carcinoma 13. Small cell carcinoma
3. Mucinous tumor, BL 14. Mature teratoma
4. Mucinous carcinoma 15. Immature teratoma
5. Endometrioid tumor, BL 16. Dysgerminoma
6. Endometrioid carcinoma 17. Embryonal carcinoma
7. Clear cell tumor, BL 18. Yolk sac tumor
8. Clear cell carcinoma 19. Granulosa cell tumor, Juvenile
9. Brenner tumor, BL 20. Granulosa cell tumor, adult
10. Malignant Brenner tumor 21. Malignant lymphoma
11. Malignant mixed Müllerian tumor 22. Others

- E. Histologic Grade: 2
1. Well 2. Moderate 3. Poorly differentiated
F. Vascular Invasion: 1. Yes 2. No
G. Tumor capsule: 2. Intact 2. Ruptured
H. Surface implants: 1
1. Invasive 2. Non-invasive 3. Not present

- I. Surface implants:
I1. Uterus: 1 1. Yes 2. No
I2. Fallopian tubes: 1 1. Yes 2. No
I3. Omentum: 1 1. Yes 2. No
I4. Peritoneal metastasis beyond the pelvis: 3
1. Microscopic 2. Less than 2 cms 3. More than 2 cms

- J. Associated other lesion: NA
1. Endometriosis.
2. Abnormalities of surface epithelium or surface epithelial inclusion.
3. Others.

- K. Malignant cells in ascites or peritoneal washing: 1 1. Yes 2. No

- L. Nodes Involved: NA

L1. Number of positive lymph nodes: NA

L2. Total number of lymph nodes examined: 0

L3. Pelvic:	Right: # positive/total #	Left: # positive/total #
L4. Obturator:	Right: # positive/total #	Left: # positive/total #
L5. Common iliac:	Right: # positive/total #	Left: # positive/total #
L6. External iliac:	Right: # positive/total #	Left: # positive/total #
L7. Para-aortic:	Right: # positive/total #	Left: # positive/total #
L8. Inguinal:	Right: # positive/total #	Left: # positive/total #

- M. Extracapsular lymph node spread

1. Yes 2. No

N. TNM Stage: T 3c N X M X

O. FIGO Stage: IIIc

ICD - 0 - 3

Carcinoma, serous, papillary 8461/3
Site: ovary, NOS C56.9

hw
1/24/15

[page 2 of 2]
FINAL DIAGNOSIS:

- PART 1: SIGMOID, NODULE, RESECTION -
PAPILLARY SEROUS CARCINOMA.**
- PART 2: FALLOPIAN TUBE AND OVARY, RIGHT, RESECTION -
PAPILLARY SEROUS CARCINOMA OF OVARY.**
- PART 3: OVARY AND FALLOPIAN TUBE, LEFT, RESECTION -
PAPILLARY SEROUS CARCINOMA OF OVARY.**
- PART 4: UTERUS, HYSTERECTOMY -**
A. TRANSUTERINE PENETRATION OF PAPILLARY SEROUS CARCINOMA INTO THE UTERINE CORPUS.
B. SQUAMOUS EPITHELIAL INCLUSION CYST OF SURFACE.
- PART 5: TUMOR, CUL-DE-SAC, DEBULKING -
PAPILLARY SEROUS CARCINOMA.**
- PART 6: MESENTERY, SIGMOID, RESECTION -
PAPILLARY SEROUS CARCINOMA.**
- PART 7: COLON, SIGMOID, RESECTION -
COLON WITH PAPILLARY SEROUS CARCINOMA, PENETRATING INTO MUSCULARIS PROPRIA.**
- PART 8: OMENTUM, RESECTION -
PAPILLARY SEROUS CARCINOMA.**
- PART 9: TUMOR, RIGHT GUTTER, DEBULKING -
PAPILLARY SEROUS CARCINOMA.**
- PART 10: TUMOR, MORRISON POUCH, DEBULKING -
PAPILLARY SEROUS CARCINOMA.**

Source: NCI Genomic Data Commons file 767025e9-b85d-4a32-90df-ee9d67e2bf0f (TCGA-61-1916.3236F7A0-4D42-4E68-B49A-56490EC92FB1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).